FM case AD11084 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors.
https://portal.gdc.cancer.gov/cases/e9d381c9-c8b6-435f-9af8-8a6ba0a95140

Male, 49.2 years: Paraganglioma, NOS (ICD-O-3 8680/1); metastasis biopsied or resected from the mediastinum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
